Gene-level copy-number profile of tumor specimen TCGA-KN-8426-01A from TCGA case TCGA-KN-8426, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.2 years (18,345 days).
Specimen TCGA-KN-8426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.eeb8de18-ddb8-4a4a-aaff-081d3d725c05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KN-8426-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03f8ff70-1c2c-486d-bec0-7520a35a6276

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 31,691; copy number 3: 5,472; copy number 4: 19,694; copy number 5: 156; copy number 6: 1,273; copy number 8: 1,376; copy number 9: 158.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KN-8426-01A-11D-2308-01): tumor purity 0.87, ploidy 1.53, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,963 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:14,470,465–14,888,169, 1 gene, copy number 5 (within-gene range 3–5): LINC00504.
- chr4:14,690,710–26,113,839, 121 genes, copy number 5 (broad region; genes not listed).
- chr4:28,225,969–33,400,679, 34 genes, copy number 5: AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2.
- chr7:65,647,010–65,770,810, 1 gene, copy number 6 (within-gene range 4–6): AC073107.1.
- chr7:65,751,142–138,701,362, 1,272 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
